Somatic mutation profile of tumor specimen ALCH-B2PY-TTR1-A (aliquot ALCH-B2PY-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B2PY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.6 years (22,118 days).
Specimen ALCH-B2PY-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695e223d-2194-4d08-8122-a58bd6e0e325.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PY-NB1-A (Blood Derived Normal), aliquot ALCH-B2PY-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9073a9fd-bbc7-402b-9fe5-9362e71a5979

The open-access MAF lists 32 somatic variants for this specimen: 15 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 10, Intron 4, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 25/192 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASIC1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.086); catalogued as rs373616682; called by mutect2, varscan2
- CLCNKB | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs1384476495, COSV65161209; called by muse, mutect2, varscan2
- CPA1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1186893434; called by muse, mutect2, varscan2
- CRYBB3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs374984300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARS2 | c.534C>A p.Y178* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV51172499; called by muse, mutect2
- NCAPD2 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780783630; called by mutect2, varscan2
- NRP1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as rs1564388011; called by muse, mutect2
- NUGGC | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.123); catalogued as rs371363580, COSV58439272; called by muse, mutect2, varscan2
- ZNF667 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.212); catalogued as rs772689155; called by muse, mutect2
- MTAP | c.347+2T>G p.X116_splice | Splice Site (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- MUC1 | c.3244G>A p.E1082K (on ENST00000611571 / NM_001371720.1; = p.E93K on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PPP1R10 | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); called by muse, varscan2
- RDH11 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, varscan2
- TLR4 | c.846T>A p.N282K (on ENST00000355622 / NM_138554.5; = p.N242K on NM_003266.4) | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRE1 | c.2643C>T p.S881= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs745580800, COSV99166115; called by muse, mutect2, varscan2
- CALR3 | c.723C>T p.S241= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs753171373, COSV99522002; called by muse, mutect2, varscan2
- HTR2C | c.1206C>T p.A402= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV52208035; called by muse, varscan2
- IKZF3 | c.1224G>A p.L408= | Silent (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- ITGAM | c.1110G>T p.G370= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- NPAS2 | c.735C>T p.D245= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs763776277, COSV100176839; called by muse, varscan2
- NRXN3 | c.1383C>T p.S461= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs1048663441; called by muse, mutect2, varscan2
- NTRK2 | c.2202C>T p.S734= (on ENST00000323115 / NM_001369534.1; = p.S750= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs369724047, COSV99451817; called by muse, mutect2, varscan2
- PHTF1 | c.1713C>T p.A571= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs1173142003; called by muse, mutect2, varscan2
- RAB6D | c.612G>C p.G204= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, varscan2
- GPT | c.252+24G>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- GRAMD2A | c.134+348G>A | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as rs903824676; called by muse, mutect2, varscan2
- IGFALS | c.*55C>T | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, varscan2
- LRRC49 | c.-23C>T | 5'UTR (SNP) | VAF 14/186 reads (8%) | catalogued as rs1274864292; called by muse, mutect2
- MRPL52 | c.157+779T>G | Intron (SNP) | VAF 10/277 reads (4%) | called by muse, mutect2
- MTHFD2L | chr4:74157715 C>A | 5'Flank (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- RABGAP1L | c.1711-89470G>A | Intron (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
